Somatic mutation profile of tumor specimen MP2PRT-PAVTJD-TMP1-A (aliquot MP2PRT-PAVTJD-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVTJD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (983 days).
Specimen MP2PRT-PAVTJD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddbf876d-5e03-4fe8-806e-8199e28dc304.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVTJD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVTJD-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e41d37d0-2bc9-4d4e-a7f5-66cd77a26c7b

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 36/347 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 59/346 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- B4GALNT4 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 224/629 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as rs774400785, COSV57322543; called by muse, mutect2, varscan2
- CAMTA1 | c.2239G>A p.V747M | Missense Mutation (SNP) | VAF 140/709 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.572); catalogued as rs368952127; called by muse, mutect2, varscan2
- CRB2 | c.2408C>T p.A803V | Missense Mutation (SNP) | VAF 180/439 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs932396631, COSV63503099; called by muse, varscan2
- RASA2 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 170/376 reads (45%) | catalogued as rs755848394, COSV53935952; called by muse, mutect2, varscan2
- ZNF337 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 33/706 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200119232, COSV53323340; called by muse, mutect2
- FAM151B | c.323C>A p.A108E | Missense Mutation (SNP) | VAF 111/256 reads (43%) | SIFT tolerated (0.99); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FBXW11 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 124/333 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO1H | c.1915G>T p.A639S | Missense Mutation (SNP) | VAF 110/272 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- TWF1 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDR | c.831A>G p.L277= | Silent (SNP) | VAF 15/404 reads (4%) | called by muse, mutect2
- PYGL | c.1389C>T p.I463= | Silent (SNP) | VAF 131/354 reads (37%) | catalogued as rs199688614, COSV53584186; called by muse, mutect2, varscan2
- TNFRSF11B | c.1011C>T p.G337= | Silent (SNP) | VAF 17/593 reads (3%) | catalogued as rs939402517, COSV52070020; called by muse, mutect2
- TNXB | c.4365C>A p.P1455= (on ENST00000647633; = p.P1208= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/562 reads (4%) | catalogued as COSV64481388; called by muse, mutect2
